CCDI case PBBJUK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/346986b6-d019-407d-a544-1cbef63f80db

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 25.4 years (9,261 days).

Biospecimens (3 samples)
- Sample 0DA68Z: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DA690: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DA691: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
